Gene-level copy-number profile of tumor specimen TCGA-JU-AAVI-01A from TCGA case TCGA-JU-AAVI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 61.0 years (22,289 days).
Specimen TCGA-JU-AAVI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.f3c19064-fbab-4608-9f18-1478e3c50056.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JU-AAVI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75f0ef24-f679-4168-90e5-044cf25c0e5a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,364; copy number 2: 27,648; copy number 3: 15,754; copy number 4: 11,738; copy number 5: 670; copy number 6: 1,088; copy number 7: 377; copy number 8: 60; copy number 10: 68; copy number 12: 900; copy number 13: 40; copy number 14: 56; copy number 43: 22; copy number 48: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JU-AAVI-01A-11D-A402-01): tumor purity 0.64, ploidy 1.63, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:27,330,827–27,506,769, 5 genes: CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C.
- chr11:27,514,970–27,521,726, 2 genes: MIR8087, RNA5SP339.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,257 genes in 57 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,491,636–40,423,326, 40 genes, copy number 6 (within-gene range 4–6): BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1.
- chr1:42,658,335–43,156,396, 25 genes, copy number 6–8: PPIH, AC098484.4, AC098484.2, YBX1, CLDN19, P3H1, C1orf50, AC098484.3, AC098484.1, TMEM269, SVBP, ERMAP, AL512353.1, ZNF691, AL512353.2, MKRN8P, ATP6V1E1P1, SLC2A1, ATP6V0CP4, SLC2A1-AS1, AC099795.1, RNU6-880P, U6, AL161637.1, FAM183A.
- chr1:43,383,917–43,946,551, 20 genes, copy number 6: MED8, MED8-AS1, SZT2, SZT2-AS1, MIR6735, HYI, HYI-AS1, PTPRF, KDM4A, AL451062.2, KDM4A-AS1, ST3GAL3, ST3GAL3-AS1, U6, AL451062.1, MIR6079, SHMT1P1, ARTN, AL357079.1, AL357079.3.
- chr1:44,390,722–44,986,722, 25 genes, copy number 6 (within-gene range 4–6): RNU6-369P, RNF220, MIR5584, TMEM53, ARMH1, RNU5F-1, RNU5D-1, KIF2C, AL592166.1, RPS8, SNORD55, SNORD46, SNORD38A, SNORD38B, SNORD38B, RPS15AP11, BEST4, PLK3, TCTEX1D4, BTBD19, PTCH2, RNU5E-6P, AL136380.1, EIF2B3, RNA5SP47.
- chr1:119,886,304–120,176,520, 6 genes, copy number 5: NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B.
- chr1:224,896,262–225,882,380, 13 genes, copy number 5 (within-gene range 3–5): DNAH14, LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A.
- chr2:38,814–38,067,142, 628 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr2:112,912,971–113,756,693, 38 genes, copy number 7: IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782.
- chr2:184,049,467–196,068,837, 131 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:56,620,133–57,693,077, 25 genes, copy number 6 (within-gene range 2–6): TASOR, ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1, HESX1, APPL1, ASB14, AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, AC092418.2, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1.
- chr3:169,083,499–169,998,373, 24 genes, copy number 5 (within-gene range 3–5): MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1.
- chr5:9,789,295–10,777,062, 42 genes, copy number 7 (within-gene range 4–7): AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr5:60,699,729–63,302,056, 35 genes, copy number 6: AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057, ZSWIM6, AC122718.2, AC122718.1, RPL3P6, C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1, AC008877.1, RN7SKP157, KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3, AC114982.1, RPL35AP14, LRRC70, ISCA1P1, AC113420.1, AC025445.1.
- chr5:149,694,237–150,796,734, 35 genes, copy number 6: AC022100.1, U3, RN7SL868P, PPARGC1B, MIR378A, PDE6A, MFFP2, Y_RNA, SLC26A2, TIGD6, HMGXB3, AC011406.1, RPS20P4, CSF1R, RPL7P1, Y_RNA, PDGFRB, CDX1, SLC6A7, CAMK2A, ARSI, TCOF1, CD74, AC011388.1, RPS14, NDST1-AS1, NDST1, SYNPO, AC011383.1, AC008453.2, MYOZ3, AC008453.1, RBM22, DCTN4, SMIM3.
- chr5:175,628,188–175,958,538, 6 genes, copy number 6: RN7SKP148, HRH2, RNU6-226P, CPLX2, AC138965.2, AC138965.1.
- chr5:179,492,076–181,342,213, 93 genes, copy number 5 (broad region; genes not listed).
- chr6:6,346,465–7,347,446, 22 genes, copy number 5–6 (within-gene range 2–6): LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4.
- chr6:118,548,296–119,182,745, 10 genes, copy number 5 (within-gene range 2–5): PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B.
- chr7:24,537,332–25,500,443, 19 genes, copy number 6: RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2.
- chr7:115,833,273–118,513,830, 56 genes, copy number 10: Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, AC002529.1.
- chr8:119,416,446–120,373,573, 16 genes, copy number 8: CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:127,578,473–128,388,636, 17 genes, copy number 48 (within-gene range 3–48): AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1.
- chr10:118,932,674–120,070,159, 30 genes, copy number 6: LDHAP5, NANOS1, EIF3A, SNORA19, AL355598.1, AL355598.2, DENND10, SFXN4, PRDX3, GRK5, GRK5-IT1, RN7SL749P, AL583824.1, MIR4681, RGS10, AC012468.1, TIAL1, RAD1P1, RPS8P4, BAG3, TXNP1, INPP5F, RN7SL846P, PHACTR2P1, AL133461.1, MCMBP, SEC23IP, MIR4682, NACAP2, AL355298.1.
- chr11:35,132,655–36,232,136, 22 genes, copy number 43 (within-gene range 2–43): AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973.
- chr12:52,821,408–53,142,327, 17 genes, copy number 5: KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1.
- chr13:113,105,788–113,928,991, 35 genes, copy number 6: F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565.
- chr14:102,224,500–102,730,561, 12 genes, copy number 5 (within-gene range 2–5): MOK, ZNF839, CINP, TECPR2, RNU6-244P, ANKRD9, MIR4309, LINC02323, RN7SL546P, RCOR1, RPL23AP11, Y_RNA.
- chr14:105,126,750–106,875,071, 218 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).
- chr16:58,496,908–58,734,342, 11 genes, copy number 5: RNU6-103P, SETD6, CNOT1, AC009118.3, SNORA46, SNORA50A, SNORA50A, AC010287.1, SLC38A7, AC012183.1, GOT2.
- chr16:68,573,782–70,079,624, 60 genes, copy number 7: AC126773.3, AC126773.6, AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429, AC099314.1, FTLP14, TANGO6, Y_RNA, U7, AC009137.1, AC009137.2, RNU6-898P, AC009027.1, RPS2P45, HAS3, DERPC, CHTF8, UTP4, RNU6-22P, SNTB2, Y_RNA, AC026474.1, AC026464.4, VPS4A, COG8, PDF, AC026464.6, AC026464.3, AC026464.1, NIP7, TMED6, TERF2, CYB5B, AC026464.5, AC026464.2, NFAT5, MIR1538, AC009032.1, AC012321.1, NQO1, AC092115.2, AC092115.3, NOB1, AC092115.1, WWP2, SNORA62, MIR140, CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1.
- chr16:71,777,603–72,225,144, 19 genes, copy number 6: AC010653.3, AC010653.1, ATXN1L, IST1, AC010653.2, ZNF821, AC009127.1, PKD1L3, RPL39P31, AC009127.2, ATP5F1AP3, DHODH, TXNL4B, HP, HPR, AC009087.1, DHX38, PMFBP1, AC009075.1.
- chr17:50,797,366–51,521,401, 23 genes, copy number 6: AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48.
- chr17:59,331,655–60,422,470, 44 genes, copy number 6 (within-gene range 4–6): YPEL2, AC091059.2, MIR4729, AC091059.1, LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42.
- chr17:75,500,261–76,619,128, 67 genes, copy number 5 (broad region; genes not listed).
- chr18:48,673,575–49,013,819, 6 genes, copy number 5 (within-gene range 3–5): AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3.
- chr19:19,063,994–45,651,805, 994 genes, copy number 7–14 (within-gene range 2–14) (broad region; genes not listed).
- chr20:87,250–13,821,580, 279 genes, copy number 5–8 (broad region; genes not listed).
- chr20:31,485,778–31,723,989, 14 genes, copy number 7: LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr20:53,668,697–54,070,594, 7 genes, copy number 6: RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756.
- chr20:62,037,429–62,762,771, 40 genes, copy number 6 (within-gene range 4–6): AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2.

Autosomal genes at a single copy (total copy number 1): 1,337. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
